Gene-level copy-number profile of tumor specimen TCGA-DK-A1A6-06A from TCGA case TCGA-DK-A1A6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.5 years (19,554 days).
Specimen TCGA-DK-A1A6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.db4348f1-e8d7-4ff5-bd35-effdce348f90.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1A6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e27446d-da63-489b-bc46-96da3fbc6b0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,470; copy number 2: 7,220; copy number 3: 23,938; copy number 4: 18,058; copy number 5: 3,477; copy number 6: 3,074; copy number 7: 1,077; copy number 8: 284; copy number 9: 126; copy number 10: 158; copy number 11: 9; copy number 12: 137; copy number 14: 18; copy number 15: 96; copy number 16: 40; copy number 23: 10; copy number 34: 35; copy number 47: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1A6-06A-11D-A42D-01): tumor purity 0.53, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,466 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,409,565–32,605,941, 54 genes, copy number 7–14 (within-gene range 3–14): SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1, AL354919.1, AL136115.2, PTP4A2, AL136115.1, AL136115.3, KHDRBS1, AL445248.1, TMEM39B, MIR5585, Metazoa_SRP, KPNA6, AL049795.2, TXLNA, CCDC28B, AL049795.1, IQCC, DCDC2B, TMEM234, EIF3I, MTMR9LP, FAM167B, LCK, Metazoa_SRP, Y_RNA, HDAC1, MARCKSL1, AL109945.1, TSSK3, FAM229A, BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A.
- chr2:8,461,703–9,934,416, 30 genes, copy number 7 (within-gene range 5–7): LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B.
- chr2:97,618,638–102,736,888, 94 genes, copy number 9–12 (broad region; genes not listed).
- chr2:157,033,837–164,352,223, 100 genes, copy number 7–10 (broad region; genes not listed).
- chr3:14,394,648–14,394,757, 1 gene, copy number 9: RNA5SP124.
- chr3:42,051,181–42,051,694, 1 gene, copy number 7: AC093414.1.
- chr3:82,319,172–90,261,708, 53 genes, copy number 7: RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:20,251,905–20,620,561, 1 gene, copy number 7 (within-gene range 4–7): SLIT2.
- chr4:20,528,275–20,752,907, 2 genes, copy number 7: MIR218-1, PACRGL.
- chr4:20,766,808–20,767,372, 1 gene, copy number 7: AC097505.1.
- chr6:13,547,704–13,826,574, 8 genes, copy number 7: RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1.
- chr6:16,232,231–23,972,941, 87 genes, copy number 8–12 (within-gene range 8–14) (broad region; genes not listed).
- chr6:26,269,405–27,897,566, 83 genes, copy number 7 (broad region; genes not listed).
- chr8:92,668,660–102,688,906, 222 genes, copy number 7–10 (broad region; genes not listed).
- chr8:106,215,763–106,272,902, 3 genes, copy number 7: SLC16A14P1, AC027031.1, AC027031.2.
- chr8:113,438,334–126,329,538, 162 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr10:46,233,885–46,537,864, 10 genes, copy number 8 (within-gene range 4–8): ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr11:66,291,894–70,189,528, 167 genes, copy number 7–47 (within-gene range 2–47) (broad region; genes not listed).
- chr12:82,223,681–83,172,740, 11 genes, copy number 7: CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr13:19,026,001–19,032,626, 2 genes, copy number 16 (within-gene range 5–16): GTF2IP3, AL137001.1.
- chr13:30,456,704–31,846,539, 24 genes, copy number 9 (within-gene range 6–9): HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1.
- chr13:31,952,580–31,975,448, 3 genes, copy number 9: EEF1DP3, AC002525.1, Metazoa_SRP.
- chr14:21,200,079–21,206,900, 1 gene, copy number 7 (within-gene range 3–7): LINC00641.
- chr17:38,297,023–41,668,031, 200 genes, copy number 8–15 (broad region; genes not listed).
- chr17:71,097,774–72,058,073, 8 genes, copy number 8: CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152.
- chr17:72,072,333–72,103,035, 1 gene, copy number 8 (within-gene range 5–8): LINC02097.
- chr19:47,745,546–47,768,840, 3 genes, copy number 9: NOP53, SNORD23, NOP53-AS1.
- chr19:56,922,018–58,605,223, 134 genes, copy number 8–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
